Somatic mutation profile of tumor specimen TCGA-AP-A0LE-01A (aliquot TCGA-AP-A0LE-01A-11D-A127-09) from TCGA case TCGA-AP-A0LE, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 57.4 years (20,967 days).
Specimen TCGA-AP-A0LE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5091050-6cdc-4c39-8a80-af0081080a20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A0LE-10A (Blood Derived Normal), aliquot TCGA-AP-A0LE-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db895392-a810-4e22-980a-7e163bfa5acc

The open-access MAF lists 655 somatic variants for this specimen: 513 protein-altering or splice-affecting, 130 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 313, Silent 130, Frame Shift Del 123, Frame Shift Ins 32, Nonsense Mutation 25, Splice Site 8, Splice Region 6, In Frame Del 6, Intron 6, 3'UTR 3, 5'Flank 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTA1 | c.243G>A p.W81* | Nonsense Mutation (SNP) | VAF 17/24 reads (71%) | catalogued as rs886039302, COSV64203178; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 22/44 reads (50%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- BRCA1 | c.329dup p.E111Gfs*3 | Frame Shift Ins (INS) | VAF 185/495 reads (37%) | catalogued as rs80357604; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 26/62 reads (42%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.109T>C p.S37P | Missense Mutation (SNP) | VAF 22/45 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121913228, COSV62688488, COSV62688537, COSV62706597; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXL3 | c.884del p.L295Yfs*25 | Frame Shift Del (DEL) | VAF 50/96 reads (52%) | catalogued as rs764008859; ClinVar: pathogenic; called by mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs746105983; ClinVar: pathogenic; called by pindel, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 53/110 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 37/74 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1057519942, COSV55881590; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 48/102 reads (47%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 20/44 reads (45%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 56/133 reads (42%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AAMP | c.44del p.P15Hfs*5 | Frame Shift Del (DEL) | VAF 8/17 reads (47%) | catalogued as rs751284215; called by mutect2, varscan2
- ABCA13 | c.12547G>A p.G4183R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.077); catalogued as COSV71286010; called by muse, mutect2, varscan2
- ABL2 | c.1273G>A p.V425M (on ENST00000502732 / NM_007314.4; = p.V410M on NM_005158.5) | Missense Mutation (SNP) | VAF 99/159 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61012729; called by muse, mutect2, varscan2
- AC004922.1 | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs1436553465, COSV53556297; called by muse, mutect2, varscan2
- ACIN1 | c.1340dup p.V448Cfs*9 | Frame Shift Ins (INS) | VAF 26/65 reads (40%) | catalogued as rs748065675; called by mutect2, varscan2
- ACO1 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs773392518, COSV59379182; called by muse, mutect2, varscan2
- ACOT4 | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.276); catalogued as rs201028153, COSV58335585; called by muse, mutect2, varscan2
- ADAT2 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV52794040; called by muse, mutect2, varscan2
- ADCY6 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751759088, COSV57167148; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 21/48 reads (44%) | catalogued as rs760140619; called by mutect2, varscan2
- AGO2 | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs758618443, COSV55046594; called by muse, mutect2, varscan2
- AHI1 | c.2506A>T p.K836* | Nonsense Mutation (SNP) | VAF 69/146 reads (47%) | catalogued as COSV55626204; called by muse, mutect2, varscan2
- AMOTL2 | c.2224C>T p.P742S (on ENST00000422605; = p.P743S on NM_016201.4) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV51438598; called by muse, mutect2, varscan2
- ANGPT4 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs963850145, COSV67921254; called by muse, mutect2, varscan2
- ANK1 | c.4307G>A p.R1436Q | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as rs1460910760, COSV55878923; called by muse, mutect2, varscan2
- ANKRD35 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs782131391, COSV62909596; called by muse, mutect2, varscan2
- APBA1 | c.2081C>T p.A694V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779985443, COSV55225775; called by muse, mutect2, varscan2
- APEX2 | c.179T>C p.L60P | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV66623911; called by muse, varscan2
- ARFGEF1 | c.2945G>A p.C982Y | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.957); catalogued as COSV51606404; called by muse, mutect2, varscan2
- ARFGEF2 | c.3533G>A p.R1178H | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.819); catalogued as rs748965329, COSV64211768; called by muse, mutect2, varscan2
- ARHGAP32 | c.3176T>C p.L1059S (on ENST00000310343 / NM_001378025.1; = p.L710S on NM_014715.4) | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.062); catalogued as COSV59846102; called by muse, mutect2, varscan2
- ARNT | c.2113+1G>A p.X705_splice | Splice Site (SNP) | VAF 67/93 reads (72%) | catalogued as COSV62230344; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 150/319 reads (47%) | catalogued as rs746676748; called by mutect2, varscan2
- ATM | c.4845G>T p.K1615N | Missense Mutation (SNP) | VAF 23/267 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as rs888498126, COSV53737811; ClinVar: uncertain significance; called by muse, mutect2
- ATP11A | c.2259G>A p.M753I | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52109804; called by muse, mutect2, varscan2
- ATP11C | c.1242_1243del p.G415Nfs*4 | Frame Shift Del (DEL) | VAF 136/357 reads (38%) | catalogued as COSV59562207; called by mutect2, pindel, varscan2
- ATP1A3 | c.1067G>A p.R356Q (on ENST00000545399 / NM_001256214.2; = p.R343Q on NM_152296.5) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs782244845, COSV57486804; called by muse, mutect2, varscan2
- ATRX | c.5817del p.D1940Ifs*15 | Frame Shift Del (DEL) | VAF 98/562 reads (17%) | catalogued as COSV100969996; called by pindel, varscan2
- AZU1 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV52140750; called by muse, varscan2
- B4GALT2 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.907); catalogued as COSV58843313; called by muse, mutect2, varscan2
- BDH1 | c.634A>G p.K212E | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64018280; called by muse, mutect2, varscan2
- BMERB1 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV55507489; called by muse, mutect2, varscan2
- BPIFB4 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs779744515, COSV64951008; called by muse, mutect2, varscan2
- BRS3 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 76/170 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65710869; called by muse, mutect2, varscan2
- BRWD3 | c.2119G>T p.G707C | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64746721; called by muse, mutect2
- BTAF1 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56432306; called by muse, mutect2, varscan2
- BTAF1 | c.4472C>T p.A1491V | Missense Mutation (SNP) | VAF 62/125 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs987973346, COSV56430376; called by muse, mutect2, varscan2
- BTBD2 | c.1182G>A p.R394= | Splice Region (SNP) | VAF 9/56 reads (16%) | catalogued as COSV55308400; called by muse, mutect2, varscan2
- C16orf46 | c.910C>A p.L304M | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55150774; called by muse, mutect2, varscan2
- C1orf100 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as rs372630882, COSV57372500; called by muse, mutect2, varscan2
- C2orf16 | c.5010T>G p.H1670Q | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as COSV62674946; called by muse, mutect2, varscan2
- C7orf25 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV63273484; called by muse, mutect2, varscan2
- C8orf58 | c.962C>T p.A321V (on ENST00000289989 / NM_001013842.3; = p.A313V on NM_173686.3) | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.34); PolyPhen benign (0.069); catalogued as COSV51514962; called by muse, mutect2, varscan2
- C9orf131 | c.2998C>T p.Q1000* | Nonsense Mutation (SNP) | VAF 24/52 reads (46%) | catalogued as COSV56610585; called by muse, mutect2, varscan2
- CACNA1G | c.2230T>C p.Y744H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61724355; called by muse, mutect2, varscan2
- CACNA1I | c.1879C>T p.R627W | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs567197463, COSV60803130; called by muse, mutect2, varscan2
- CACNA2D4 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1372674469, COSV54948209; called by muse, mutect2, varscan2
- CALCRL | c.48del p.F16Lfs*2 | Frame Shift Del (DEL) | VAF 58/138 reads (42%) | catalogued as rs1486659949; called by mutect2, pindel, varscan2
- CAMKV | c.1271G>A p.R424K | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.017); catalogued as COSV56554950; called by muse, mutect2, varscan2
- CCAR1 | c.2255T>C p.L752P | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56268953; called by muse, mutect2, varscan2
- CCDC136 | c.20A>G p.E7G | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52798634; called by muse, mutect2, varscan2
- CCDC180 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763177962, COSV63829166; called by muse, mutect2, varscan2
- CCDC27 | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs185617592, COSV53899594; called by muse, mutect2
- CCT6A | c.820del p.I274* | Frame Shift Del (DEL) | VAF 39/101 reads (39%) | catalogued as rs1482449902; called by mutect2, pindel, varscan2
- CD163L1 | c.1952C>T p.S651F | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.48); PolyPhen benign (0.176); catalogued as COSV58014365; called by muse, mutect2, varscan2
- CDH19 | c.1937del p.G646Vfs*11 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | catalogued as COSV50983957; called by mutect2, pindel, varscan2
- CDH5 | c.1245G>T p.K415N | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV58517010; called by muse, mutect2, varscan2
- CDHR2 | c.1016T>C p.V339A | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56137165; called by muse, mutect2, varscan2
- CEACAM3 | c.581A>G p.Q194R | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.125); catalogued as COSV55761296; called by muse, mutect2, varscan2
- CECR2 | c.457G>T p.G153W | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52839462; called by muse, mutect2, varscan2
- CEP135 | c.2617-2A>G p.X873_splice | Splice Site (SNP) | VAF 32/59 reads (54%) | catalogued as COSV57259364; called by muse, mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 134/301 reads (45%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CHD1L | c.208G>T p.G70* | Nonsense Mutation (SNP) | VAF 53/185 reads (29%) | catalogued as COSV63613551; called by muse, mutect2, varscan2
- CHD7 | c.7013A>C p.Q2338P | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV71109155; called by muse, mutect2, varscan2
- CHEK1 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.312); catalogued as rs1255118863, COSV54022963, COSV54023166; called by muse, mutect2, varscan2
- CIB3 | c.550C>A p.H184N | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV53737686; called by muse, mutect2, varscan2
- CLIP4 | c.1174A>G p.T392A | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV60748656; called by muse, mutect2, varscan2
- CNKSR1 | c.1535dup p.P513Tfs*9 (on ENST00000374253 / NM_001297647.2; = p.P506Tfs*9 on NM_006314.3) | Frame Shift Ins (INS) | VAF 14/35 reads (40%) | catalogued as rs753922055; called by mutect2, varscan2
- CNTNAP5 | c.1931G>A p.G644D | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as rs748270033, COSV70482037; called by muse, mutect2, varscan2
- COBL | c.3282del p.K1094Nfs*20 | Frame Shift Del (DEL) | VAF 90/211 reads (43%) | catalogued as rs1562810271; called by mutect2, pindel, varscan2
- COL6A3 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.117); catalogued as rs547651808, COSV55086311; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- COPB1 | c.883A>G p.N295D | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51447828; called by muse, mutect2, varscan2
- CORIN | c.2572C>T p.L858F | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV56689739; called by muse, mutect2, varscan2
- CPA6 | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs769320961, COSV52726421; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 130/431 reads (30%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CRLF3 | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 51/100 reads (51%) | catalogued as rs1300240812, COSV60835616; called by muse, mutect2, varscan2
- CSMD1 | c.3079T>C p.F1027L (on ENST00000520002; = p.F1026L on NM_033225.6) | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1171901427, COSV59308349; called by muse, mutect2
- CYP1A2 | c.1447G>A p.V483M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.876); catalogued as rs143028942; called by muse, mutect2, varscan2
- CYSLTR1 | c.671dup p.N224Kfs*6 | Frame Shift Ins (INS) | VAF 42/100 reads (42%) | catalogued as rs766746913; called by mutect2, varscan2
- CYTH1 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV63119818; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | catalogued as COSV99245498; called by mutect2, varscan2
- DBH | c.671C>A p.P224H | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55040389; called by muse, mutect2, varscan2
- DCAF4L1 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV60786957; called by muse, mutect2, varscan2
- DCAF8L1 | c.725T>G p.V242G | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV71595219; called by muse, mutect2, varscan2
- DCHS1 | c.6823C>A p.P2275T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55033965; called by muse, mutect2, varscan2
- DCLRE1C | c.746G>A p.R249H (on ENST00000378278 / NM_001350965.2; = p.R134H on NM_022487.4) | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as rs374838779; called by muse, mutect2
- DCSTAMP | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV52577205; called by muse, mutect2, varscan2
- DDB2 | c.1135T>C p.S379P | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV57037828; called by muse, mutect2, varscan2
- DENND11 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.709); catalogued as rs781700741, COSV72097614; called by muse, mutect2, varscan2
- DENND2D | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62958920; called by muse, mutect2, varscan2
- DENND4C | c.2165C>T p.P722L | Missense Mutation (SNP) | VAF 56/100 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.773); catalogued as rs766191608, COSV66821944; called by muse, mutect2, varscan2
- DHRS13 | c.947G>T p.G316V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV66683874; called by muse, mutect2
- DIAPH3 | c.1297G>A p.A433T (on ENST00000400324 / NM_001042517.2; = p.A170T on NM_030932.3) | Missense Mutation (SNP) | VAF 74/154 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.567); catalogued as rs1318320950, COSV57368432; called by muse, mutect2, varscan2
- DLG5 | c.3848C>T p.P1283L | Missense Mutation (SNP) | VAF 71/165 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1282713034, COSV64947568; called by muse, mutect2, varscan2
- DMAP1 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV60000409; called by muse, mutect2
- DNAH1 | c.6683C>T p.P2228L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV70228145; called by muse, mutect2, varscan2
- DNAH10 | c.1349C>T p.P450L (on ENST00000409039; = p.P389L on NM_207437.3) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs763680952, COSV68991585; called by muse, mutect2, varscan2
- DNAJB2 | c.67T>C p.Y23H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60676339; called by muse, mutect2, varscan2
- DNM3 | c.738G>T p.K246N | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62456328; called by muse, mutect2, varscan2
- DOCK6 | c.2354G>A p.R785H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs369679393; called by muse, mutect2, varscan2
- DST | c.8189A>G p.H2730R | Missense Mutation (SNP) | VAF 97/192 reads (51%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.037); catalogued as COSV55008308; called by muse, mutect2, varscan2
- EEF2K | c.1448T>C p.V483A | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.87); PolyPhen benign (0.115); catalogued as COSV53780662; called by muse, mutect2, varscan2
- EFCAB5 | c.450del p.K150Nfs*17 | Frame Shift Del (DEL) | VAF 40/80 reads (50%) | catalogued as rs760813779; called by mutect2, varscan2
- ELFN2 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.212); catalogued as rs1411291891, COSV68744343; called by muse, mutect2, varscan2
- EPHA5 | c.2755C>T p.R919* | Nonsense Mutation (SNP) | VAF 53/126 reads (42%) | catalogued as rs146343247, COSV56666563; called by muse, mutect2, varscan2
- EPM2AIP1 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.029); catalogued as rs894471541, COSV51616766; called by muse, mutect2, varscan2
- ERBB2 | c.3238G>T p.G1080W | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV54068038; called by muse, mutect2, varscan2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 14/23 reads (61%) | catalogued as rs780487406; called by mutect2, pindel, varscan2
- ERGIC3 | c.101G>A p.S34N | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV54136999; called by muse, mutect2, varscan2
- ERGIC3 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54137011; called by muse, mutect2, varscan2
- ETNPPL | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56595423; called by muse, mutect2, varscan2
- EXO5 | c.323C>A p.P108H | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV56415563; called by muse, mutect2
- FAM135B | c.2987A>G p.Q996R | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV52717860; called by muse, mutect2, varscan2
- FAM153B | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.007); catalogued as rs1387503753; called by mutect2, varscan2
- FAM166C | c.526T>C p.Y176H | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.758); catalogued as COSV56600180; called by muse, mutect2
- FANCG | c.1351T>C p.W451R | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62720175; called by muse, mutect2
- FANCM | c.1327T>A p.F443I | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1245664522; called by muse, mutect2
- FAR2 | c.288G>C p.E96D | Missense Mutation (SNP) | VAF 84/202 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.158); catalogued as COSV51724966; called by muse, mutect2, varscan2
- FASN | c.7283G>A p.R2428H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.91); catalogued as rs745397050, COSV60753099; called by muse, mutect2, varscan2
- FASTKD2 | c.1487A>T p.E496V | Missense Mutation (SNP) | VAF 10/298 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.035); catalogued as COSV52697931; called by muse, mutect2
- FAT2 | c.7130dup p.E2378Rfs*8 | Frame Shift Ins (INS) | VAF 20/56 reads (36%) | catalogued as rs1199962794; called by mutect2, pindel, varscan2
- FAT2 | c.4280G>A p.R1427H | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs573511043, COSV55817608; called by muse, mutect2, varscan2
- FGA | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.034); catalogued as COSV57394141; called by muse, mutect2, varscan2
- FGD6 | c.3824A>G p.H1275R | Missense Mutation (SNP) | VAF 97/218 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV59692098; called by muse, mutect2, varscan2
- FILIP1L | c.2247dup p.L750Tfs*16 (on ENST00000354552 / NM_182909.3; = p.L510Tfs*16 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 99/226 reads (44%) | catalogued as rs1433753279; called by mutect2, varscan2
- FLNB | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs147001986, COSV55873758; called by muse, varscan2
- FLNB | c.5429G>A p.S1810N | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV55876338; called by muse, mutect2, varscan2
- FRAS1 | c.1887del p.K630Rfs*67 | Frame Shift Del (DEL) | VAF 25/57 reads (44%) | catalogued as rs776570778; called by mutect2, pindel, varscan2
- FREM1 | c.2899G>T p.E967* | Nonsense Mutation (SNP) | VAF 48/98 reads (49%) | catalogued as COSV66521793; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 42/92 reads (46%) | catalogued as rs756304971; called by mutect2, varscan2
- GABBR2 | c.2116G>A p.G706R | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52300277, COSV99410742; called by muse, mutect2, varscan2
- GAL3ST2 | c.119+1G>A p.X40_splice | Splice Site (SNP) | VAF 10/19 reads (53%) | catalogued as rs201322295; called by muse, mutect2, varscan2
- GCA | c.306T>C p.D102= | Splice Region (SNP) | VAF 19/60 reads (32%) | catalogued as COSV52025336; called by muse, mutect2, varscan2
- GFPT1 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 79/153 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61947517; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 66/142 reads (46%) | catalogued as rs750227570; called by mutect2, varscan2
- GMPPA | c.458G>A p.G153D | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58006595; called by muse, mutect2, varscan2
- GOT1 | c.900del p.A301Pfs*24 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as COSV65147342; called by mutect2, pindel, varscan2
- GPKOW | c.176G>T p.S59I | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV50242445; called by muse, mutect2, varscan2
- GPR137 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57401745; called by muse, mutect2, varscan2
- GPR137 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs753450610, COSV57401765; called by muse, mutect2, varscan2
- GPR37L1 | c.701G>A p.S234N | Missense Mutation (SNP) | VAF 37/50 reads (74%) | SIFT tolerated (0.63); PolyPhen benign (0.241); catalogued as COSV66162113; called by muse, mutect2, varscan2
- GPR65 | c.61T>C p.Y21H | Missense Mutation (SNP) | VAF 64/126 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50862506; called by muse, mutect2, varscan2
- GPRC6A | c.2640G>T p.M880I | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59952523; called by muse, mutect2, varscan2
- GPRIN3 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs373668813; called by muse, mutect2, varscan2
- GTF2IRD2B | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1269305151, COSV57030791; called by muse, mutect2, varscan2
- GTPBP2 | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770981387, COSV61076025; called by muse, mutect2, varscan2
- HDAC11 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776557434, COSV55472909, COSV99849929; called by muse, mutect2, varscan2
- HDLBP | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as rs754540075, COSV60493742, COSV60494369; called by muse, mutect2, varscan2
- HIRA | c.1832G>A p.S611N | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV54273958; called by muse, mutect2, varscan2
- HPSE | c.158G>A p.S53N | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.065); catalogued as COSV60986371; called by muse, mutect2, varscan2
- HSPA4L | c.1722del p.G575Efs*18 | Frame Shift Del (DEL) | VAF 38/95 reads (40%) | catalogued as rs775794446; called by mutect2, pindel, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 107/233 reads (46%) | catalogued as rs747841314; called by mutect2, varscan2
- ICE1 | c.3448G>T p.G1150C | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56822555; called by muse, mutect2, varscan2
- ICE2 | c.2510A>G p.K837R | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as rs200459430, COSV55030702; called by muse, varscan2
- IFIT2 | c.1217G>T p.R406M | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV51078517; called by muse, mutect2, varscan2
- IL1R1 | c.878T>C p.I293T | Missense Mutation (SNP) | VAF 108/226 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV52105691; called by muse, mutect2, varscan2
- IL21R | c.121A>G p.N41D | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.7); PolyPhen benign (0.046); catalogued as COSV61969678; called by muse, mutect2, varscan2
- INPPL1 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1293622519, COSV53354767, COSV53358764, COSV99996721; called by muse, mutect2, varscan2
- INPPL1 | c.3668A>G p.D1223G | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1347318499, COSV53354778; called by muse, mutect2, varscan2
- INSR | c.2332G>A p.A778T | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1327078774, COSV57160710; called by muse, mutect2, varscan2
- IRF2 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | catalogued as COSV66929184, COSV66930391; called by muse, mutect2, varscan2
- ITGA2B | c.1292G>T p.R431M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV52232129; called by muse, mutect2, varscan2
- ITGA6 | c.1208T>C p.V403A (on ENST00000442250; = p.V364A on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.511); catalogued as COSV51222561, COSV51231460; called by muse, mutect2, varscan2
- IVNS1ABP | c.1805C>T p.A602V | Missense Mutation (SNP) | VAF 140/224 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV62250842; called by muse, mutect2, varscan2
- JAG1 | c.3124C>T p.R1042C | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs778801776, COSV54755716; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | catalogued as rs755650243; called by mutect2, pindel, varscan2
- JMJD7 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767374060, COSV59823421; called by muse, mutect2, varscan2
- JPH3 | c.1856T>C p.L619P | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0.085); catalogued as COSV52466470; called by muse, varscan2
- KCNA6 | c.767del p.G256Afs*41 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | catalogued as COSV54975156, COSV99768463; called by mutect2, pindel, varscan2
- KCNMA1 | c.1189T>C p.Y397H | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV54241362; called by muse, mutect2, varscan2
- KCNV2 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.782); catalogued as rs770032221, COSV66055901; ClinVar: uncertain significance; called by muse, mutect2
- KCTD19 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV58572238; called by muse, mutect2, varscan2
- KIAA1217 | c.3982T>A p.S1328T | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.67); PolyPhen benign (0.026); catalogued as COSV56815313; called by muse, mutect2, varscan2
- KIAA1549L | c.2180C>T p.A727V (on ENST00000321505; = p.A1024V on NM_012194.3) | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.138); catalogued as COSV55772077; called by muse, mutect2, varscan2
- KIAA1614 | c.149del p.P50Qfs*15 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs771572430; called by mutect2, varscan2
- KIF17 | c.2075G>A p.G692D | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV56117475; called by muse, mutect2, varscan2
- KIF5A | c.1882T>C p.S628P | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV54053604; called by muse, mutect2
- KLC2 | c.451T>C p.S151P | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV57582192; called by muse, mutect2, varscan2
- KLHL21 | c.1711C>T p.R571C | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs927653533, COSV66553318; called by muse, mutect2, varscan2
- KMT2B | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as COSV52890122; called by muse, mutect2, varscan2
- KRT3 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 82/151 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.143); catalogued as rs757365353, COSV58815223; called by muse, mutect2, varscan2
- KRT71 | c.1469T>C p.V490A | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV57289749; called by muse, mutect2, varscan2
- LARP1 | c.776T>C p.M259T (on ENST00000518297 / NM_033551.3; = p.M182T on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.119); catalogued as COSV60426165; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 111/264 reads (42%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LCP2 | c.186G>A p.V62= | Splice Region (SNP) | VAF 44/91 reads (48%) | catalogued as COSV50448718, COSV50451838; called by muse, mutect2, varscan2
- LGR4 | c.2608G>C p.V870L | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV58725573; called by muse, mutect2, varscan2
- LILRB5 | c.1762del p.L588Wfs*34 (on ENST00000449561 / NM_001081442.3; = p.L587Wfs*34 on NM_006840.5) | Frame Shift Del (DEL) | VAF 23/53 reads (43%) | catalogued as rs775329343; called by mutect2, pindel, varscan2
- LIMK1 | c.1186G>A p.V396M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60280807; called by muse, mutect2, varscan2
- LITAF | c.370C>A p.L124M | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV59655469; called by muse, mutect2, varscan2
- LMAN1L | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV59001616; called by muse, mutect2, varscan2
- LMO4 | c.229T>C p.Y77H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65170213; called by muse, mutect2, varscan2
- LOXL4 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs199516998, COSV53256165; called by muse, mutect2
- LPAR3 | c.139del p.S47Lfs*9 | Frame Shift Del (DEL) | VAF 30/64 reads (47%) | catalogued as rs762083435; called by mutect2, varscan2
- LRCH2 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.288); catalogued as COSV57748865; called by muse, mutect2, varscan2
- LRFN5 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs778299563, COSV53251670; called by muse, mutect2, varscan2
- LRRC47 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 5/9 reads (56%) | catalogued as COSV65562312; called by muse, mutect2, varscan2
- LRRC61 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs759257308, COSV56231064; called by muse, mutect2, varscan2
- LRRCC1 | c.2781A>T p.K927N | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64483076; called by muse, mutect2, varscan2
- LRRTM1 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.171); catalogued as rs1187860249, COSV54438118, COSV54440170; called by muse, mutect2, varscan2
- LTB4R | c.178C>A p.L60M | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51865321; called by muse, mutect2, varscan2
- MACF1 | c.17054C>A p.A5685D (on ENST00000372915; = p.A3727D on NM_012090.5) | Missense Mutation (SNP) | VAF 43/93 reads (46%) | catalogued as COSV57116943; called by muse, mutect2, varscan2
- MAP4K1 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.521); catalogued as rs531344324, COSV67708524, COSV67709841; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1537-2A>G p.X513_splice | Splice Site (SNP) | VAF 9/20 reads (45%) | catalogued as COSV51718930; called by muse, mutect2, varscan2
- MARK4 | c.1387G>T p.G463W | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV53463022; called by muse, mutect2, varscan2
- MB21D2 | c.368C>A p.P123Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66662814; called by muse, mutect2, varscan2
- MBD1 | c.1123C>T p.R375C (on ENST00000269468 / NM_001323950.1; = p.R352C on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54000042; called by muse, mutect2, varscan2
- MBNL3 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100898493, COSV63730710; called by muse, mutect2, varscan2
- MEI1 | c.1075del p.S359Pfs*13 | Frame Shift Del (DEL) | VAF 90/238 reads (38%) | catalogued as rs1280411643; called by mutect2, pindel, varscan2
- METRNL | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 12/19 reads (63%) | catalogued as COSV60760219; called by muse, mutect2, varscan2
- METTL8 | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 114/256 reads (45%) | catalogued as rs779685244, COSV64548954; called by muse, mutect2, varscan2
- MMP3 | c.190del p.I64Sfs*12 | Frame Shift Del (DEL) | VAF 32/80 reads (40%) | catalogued as rs782038929; called by mutect2, pindel, varscan2
- MPPED2 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV63897544; called by muse, mutect2, varscan2
- MRPL15 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 88/183 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52637316; called by muse, mutect2, varscan2
- MRPS22 | c.656G>A p.S219N (on ENST00000310776 / NM_001363893.1; = p.S220N on NM_020191.4) | Missense Mutation (SNP) | VAF 84/181 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV60349605; called by muse, mutect2, varscan2
- MTOR | c.3371C>T p.A1124V | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.305); catalogued as rs759748160, COSV63870105; called by muse, mutect2, varscan2
- MUC16 | c.31734G>T p.E10578D | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV67459177; called by muse, mutect2, varscan2
- MUC5B | c.11006G>A p.G3669D | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as COSV71591313; called by muse, mutect2, varscan2
- MUC6 | c.3096G>T p.K1032N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV70139445; called by muse, mutect2, varscan2
- MYBPC1 | c.1391G>T p.W464L (on ENST00000550270 / NM_206820.2; = p.W489L on NM_002465.4) | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs1302368356, COSV62252351; called by muse, mutect2, varscan2
- MYH10 | c.310A>G p.N104D | Missense Mutation (SNP) | VAF 91/194 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52598781; called by muse, mutect2, varscan2
- MYH2 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.101); catalogued as COSV55435640; called by muse, mutect2, varscan2
- MYLK | c.1478A>G p.Q493R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV60608485; called by muse, mutect2, varscan2
- NAALADL2 | c.1444_1445del p.K482Efs*26 | Frame Shift Del (DEL) | VAF 50/125 reads (40%) | catalogued as COSV69155283; called by mutect2, pindel, varscan2
- NAV1 | c.2877G>T p.K959N | Missense Mutation (SNP) | VAF 58/99 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV55216396; called by muse, mutect2, varscan2
- NAV1 | c.4509del p.E1504Rfs*19 | Frame Shift Del (DEL) | VAF 34/77 reads (44%) | catalogued as rs1558191440; called by mutect2, pindel, varscan2
- NBEAL2 | c.7541G>A p.G2514D | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs776407354, COSV52756499; called by muse, mutect2, varscan2
- NCAPG2 | c.2404C>A p.L802I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV51986677; called by muse, mutect2, varscan2
- NCK2 | c.1030A>G p.I344V | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51890510; called by muse, mutect2, varscan2
- NCOA6 | c.5785G>A p.A1929T | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs142121277, COSV62865042; called by muse, mutect2, varscan2
- NET1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs776534266, COSV61791214; called by muse, mutect2, varscan2
- NKRF | c.1538A>C p.K513T | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV58661380; called by muse, mutect2, varscan2
- NLRC4 | c.1918C>A p.P640T | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV61592203; called by muse, mutect2
- NLRP7 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs778846440, COSV60173062; called by muse, mutect2, varscan2
- NMNAT2 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.3); PolyPhen benign (0.067); catalogued as rs201215509, COSV54267750; called by muse, mutect2, varscan2
- NOD1 | c.2663T>C p.L888S | Missense Mutation (SNP) | VAF 100/209 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV56111976; called by muse, mutect2, varscan2
- NOD2 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.964); catalogued as rs764176270, COSV56049655; called by muse, mutect2, varscan2
- NOS1 | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV57610370; called by muse, mutect2, varscan2
- NOX4 | c.972C>G p.I324M | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV54451137; called by muse, mutect2, varscan2
- NPHP4 | c.2590C>T p.L864F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.595); catalogued as rs562743654, COSV65394386; called by muse, mutect2, varscan2
- NPR2 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as rs1041113337; called by muse, mutect2
- NR1H3 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs753126526, COSV68008155; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 64/155 reads (41%) | catalogued as rs776154715; called by mutect2, varscan2
- NRXN1 | c.3560T>A p.I1187N | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60494012; called by muse, mutect2, varscan2
- NSD3 | c.3092C>T p.T1031I | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.047); catalogued as COSV57668445; called by muse, mutect2, varscan2
- NUP205 | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53657598; called by muse, mutect2, varscan2
- NUP210 | c.1340A>G p.E447G | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV54405036, COSV54407158; called by muse, mutect2, varscan2
- ODF2L | c.1893T>C p.S631= (on ENST00000317336; = p.S615= on NM_020729.3) | Splice Region (SNP) | VAF 152/317 reads (48%) | catalogued as COSV54014958; called by muse, mutect2, varscan2
- OLFM1 | c.95A>G p.Q32R | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV52962027; called by muse, mutect2, varscan2
- OPN1LW | c.280A>G p.N94D | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64064114; called by muse, mutect2, varscan2
- OR13G1 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as rs200763482, COSV100687494, COSV62943805; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 64/112 reads (57%) | catalogued as rs761899382; called by mutect2, varscan2
- OR2M3 | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 128/404 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776150417, COSV101513532, COSV71758983; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | catalogued as rs755413956; called by mutect2, varscan2
- P2RY6 | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as rs1336910280, COSV62936252; called by muse, mutect2, varscan2
- PABPC3 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs368161941, COSV55799038; called by muse, varscan2
- PABPC5 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as rs751297464, COSV57039669; called by muse, mutect2, varscan2
- PACS2 | c.1964C>T p.A655V | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782564104, COSV57651532; called by muse, mutect2, varscan2
- PACSIN2 | c.1089_1090insA p.F364Ifs*4 | Frame Shift Ins (INS) | VAF 46/107 reads (43%) | catalogued as COSV99606837; called by mutect2, pindel, varscan2
- PACSIN2 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as rs1027154871, COSV54318314; called by muse, mutect2, varscan2
- PAPPA2 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV62776416; called by muse, mutect2, varscan2
- PCDHA3 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV63538638; called by muse, mutect2, varscan2
- PCDHB10 | c.1441G>A p.G481S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53377637, COSV53383266; called by muse, mutect2, varscan2
- PCDHB2 | c.524G>A p.S175N | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.068); catalogued as COSV52031556; called by muse, mutect2, varscan2
- PCDHB8 | c.1684G>A p.V562M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV50753540; called by muse, mutect2, varscan2
- PCDHGA2 | c.2206C>T p.Q736* | Nonsense Mutation (SNP) | VAF 27/46 reads (59%) | catalogued as COSV53928995; called by muse, mutect2, varscan2
- PCM1 | c.3850G>A p.A1284T | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59586185; called by muse, mutect2, varscan2
- PCNT | c.2840C>T p.A947V | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV64027095; called by muse, mutect2, varscan2
- PDS5B | c.3954del p.K1318Nfs*76 | Frame Shift Del (DEL) | VAF 25/50 reads (50%) | catalogued as rs747131399; called by mutect2, varscan2
- PDZD3 | c.1031G>A p.R344Q (on ENST00000531114; = p.R264Q on NM_024791.4) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); catalogued as rs749505665, COSV52703348; called by muse, mutect2, varscan2
- PGLYRP2 | c.700G>T p.G234C | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.706); catalogued as COSV52992937; called by muse, mutect2, varscan2
- PGLYRP4 | c.58T>C p.S20P | Missense Mutation (SNP) | VAF 220/346 reads (64%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV62835025; called by muse, mutect2, varscan2
- PGS1 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV53144541; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 6/8 reads (75%) | catalogued as rs769717544; called by mutect2, varscan2
- PHKB | c.2519A>G p.N840S | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV54519094; called by muse, mutect2
- PIK3C2G | c.3718C>A p.L1240M (on ENST00000676171; = p.L1199M on NM_004570.5) | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV56805356; called by muse, mutect2, varscan2
- PKD2L2 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs772979367, COSV51795011; called by muse, mutect2, varscan2
- PKHD1L1 | c.10326A>C p.P3442= | Splice Region (SNP) | VAF 12/112 reads (11%) | catalogued as rs778208608, COSV65741150; called by muse, varscan2
- PLA2G4C | c.1444T>C p.W482R | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV62784993; called by muse, mutect2, varscan2
- PLXNB3 | c.2624G>A p.S875N | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV62796788; called by muse, mutect2, varscan2
- POLR1G | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.649); catalogued as rs777786624, COSV50004031; called by muse, mutect2, varscan2
- POLR3A | c.940C>T p.Q314* | Nonsense Mutation (SNP) | VAF 31/62 reads (50%) | catalogued as COSV64930832; called by muse, mutect2, varscan2
- PPP6R3 | c.1499G>A p.C500Y (on ENST00000393800 / NM_001352375.2; = p.C449Y on NM_018312.5) | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV55724785; called by muse, mutect2
- PRDM2 | c.4420G>A p.A1474T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as rs778540114, COSV52445191, COSV52450944; called by muse, mutect2, varscan2
- PREX2 | c.1057T>C p.F353L | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55763329; called by muse, mutect2
- PRKCD | c.1300del p.D434Tfs*2 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as rs1559629912, COSV57847601; called by mutect2, pindel, varscan2
- PRKDC | c.3407G>A p.R1136H | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs781401034, COSV58044763; called by muse, mutect2, varscan2
- PRKG1 | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as rs376134488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 88/180 reads (49%) | catalogued as rs753236928; called by mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 95/177 reads (54%) | catalogued as rs781858060; called by mutect2, varscan2
- PTCH1 | c.4274C>T p.S1425L | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as rs587778630, COSV59462409; ClinVar: likely benign / uncertain significance / not provided; called by muse, mutect2, varscan2
- PTPA | c.596G>A p.C199Y (on ENST00000337738 / NM_178001.2; = p.C164Y on NM_021131.5) | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV61234598; called by muse, mutect2
- PTPRJ | c.3503T>C p.M1168T | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV69251471; called by muse, mutect2, varscan2
- PTPRK | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 117/249 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.802); catalogued as COSV100950898, COSV63895339; called by muse, mutect2, varscan2
- RAB34 | c.712+1G>A p.X238_splice | Splice Site (SNP) | VAF 6/29 reads (21%) | catalogued as rs770497617, COSV56385998; called by muse, mutect2, varscan2
- RAB3C | c.103A>G p.I35V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as rs1484314125, COSV51434771; called by muse, mutect2, varscan2
- RANBP3 | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.959); catalogued as rs763899206, COSV50380969; called by muse, mutect2, varscan2
- RBBP6 | c.*3del | Frame Shift Del (DEL) | VAF 28/70 reads (40%) | catalogued as COSV60502977, COSV60507832; called by mutect2, pindel, varscan2
- RBP5 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 31/59 reads (53%) | catalogued as rs191452484, COSV56934895; called by muse, mutect2, varscan2
- RDH5 | c.733+1G>T p.X245_splice | Splice Site (SNP) | VAF 8/12 reads (67%) | catalogued as rs987261718, COSV57676243; called by muse, mutect2, varscan2
- RGS9 | c.500+2T>C p.X167_splice | Splice Site (SNP) | VAF 43/93 reads (46%) | catalogued as COSV52224516; called by muse, mutect2, varscan2
- RHOBTB1 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 70/141 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs751927663, COSV61958256; called by muse, varscan2
- RIC1 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 127/263 reads (48%) | catalogued as COSV52608314; called by muse, mutect2, varscan2
- RIF1 | c.6730_6732del p.P2244del | In Frame Del (DEL) | VAF 50/100 reads (50%) | catalogued as rs772018521; called by mutect2, pindel, varscan2
- RLF | c.4240T>C p.C1414R | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65651441; called by muse, mutect2, varscan2
- RNF128 | c.31dup p.W11Lfs*11 | Frame Shift Ins (INS) | VAF 70/148 reads (47%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF43 | c.1322del p.P441Lfs*61 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs755967475, COSV68457961; called by mutect2, varscan2
- ROBO2 | c.3233del p.P1078Qfs*95 | Frame Shift Del (DEL) | VAF 42/86 reads (49%) | catalogued as rs745519558, COSV100168583; called by mutect2, varscan2
- ROR1 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV64283533; called by muse, mutect2, varscan2
- RPP25L | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV52407007; called by muse, mutect2, varscan2
- RPS6 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.522); catalogued as rs748611445, COSV59547763; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- S1PR3 | c.967dup p.A323Gfs*16 | Frame Shift Ins (INS) | VAF 5/23 reads (22%) | catalogued as rs779370603; called by mutect2, pindel, varscan2
- SASH1 | c.2410G>A p.V804M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.135); catalogued as rs756111132, COSV66560864; called by muse, mutect2, varscan2
- SCAF1 | c.3655G>A p.E1219K | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1330230192, COSV59190392, COSV59191056; called by mutect2, varscan2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 102/268 reads (38%) | catalogued as COSV54589079; called by mutect2, pindel, varscan2
- SCLT1 | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 186/415 reads (45%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs138724704; called by muse, mutect2, varscan2
- SCLY | c.509C>T p.A170V (on ENST00000651534; = p.A162V on NM_016510.7) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs199710272; called by muse, mutect2, varscan2
- SCN10A | c.640C>A p.L214M | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71860960; called by muse, mutect2, varscan2
- SEBOX | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV52646407; called by muse, mutect2, varscan2
- SEC16B | c.1292T>C p.I431T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV57624823; called by mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 58/104 reads (56%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA4A | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.586); catalogued as rs780337679, COSV61772489; called by muse, mutect2, varscan2
- SERPINB2 | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as COSV53072675; called by muse, mutect2, varscan2
- SETMAR | c.1228T>A p.S410T | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.343); catalogued as rs762740539, COSV62780627; called by muse, mutect2, varscan2
- SETMAR | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.18); catalogued as rs548071960, COSV62780630; called by muse, mutect2, varscan2
- SFMBT2 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868013820, COSV62808092; called by muse, mutect2, varscan2
- SFR1 | c.296A>G p.Q99R (on ENST00000369727 / NM_001002759.1; = p.Q86R on NM_145247.4) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV60478921; called by muse, mutect2, varscan2
- SGO2 | c.1943del p.F648Sfs*14 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | catalogued as rs771387868; called by mutect2, varscan2
- SGO2 | c.3191_3193del p.E1064del | In Frame Del (DEL) | VAF 6/43 reads (14%) | catalogued as rs756243045; called by pindel, varscan2
- SHOX | c.200C>A p.P67Q | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.359); catalogued as CM074511, COSV61860608; called by muse, mutect2, varscan2
- SHPRH | c.495del p.E166Nfs*3 | Frame Shift Del (DEL) | VAF 101/213 reads (47%) | catalogued as rs1469942319; called by mutect2, varscan2
- SHTN1 | c.1403T>G p.L468R | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.997); catalogued as COSV53381583; called by muse, mutect2, varscan2
- SLC17A6 | c.1468G>T p.G490* | Nonsense Mutation (SNP) | VAF 26/62 reads (42%) | catalogued as COSV54135306; called by muse, mutect2, varscan2
- SLC26A4 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs141142414, CM061988; called by muse, mutect2, varscan2
- SLC27A3 | c.2327C>T p.P776L (on ENST00000271857; = p.P648L on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV55163067; called by muse, mutect2, varscan2
- SLC35A5 | c.898del p.Y300Mfs*8 | Frame Shift Del (DEL) | VAF 39/133 reads (29%) | catalogued as rs1363537717; called by mutect2, pindel, varscan2
- SLC36A3 | c.1293G>T p.K431N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100077337, COSV58856527; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs759883814, COSV56092392; called by mutect2, varscan2
- SMARCA2 | c.4118C>G p.A1373G | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV56645984; called by muse, mutect2, varscan2
- SMG1 | c.6173C>A p.P2058Q | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67170679; called by muse, mutect2, varscan2
- SMG6 | c.628G>T p.G210W | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV53965904; called by muse, mutect2
- SNAPC3 | c.1001G>A p.C334Y | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1266099231, COSV66402699; called by muse, mutect2
- SPEN | c.9869C>T p.T3290I | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV65360456; called by muse, mutect2, varscan2
- SRSF4 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); catalogued as COSV65694403; called by muse, mutect2, varscan2
- ST3GAL2 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 12/23 reads (52%) | PolyPhen probably damaging (1); catalogued as COSV61596391; called by muse, mutect2, varscan2
- ST7L | c.1520dup p.E508Gfs*28 | Frame Shift Ins (INS) | VAF 51/137 reads (37%) | catalogued as rs1163874186; called by mutect2, pindel, varscan2
- STRIP2 | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs756286396, COSV50803855; called by muse, mutect2, varscan2
- STYXL1 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.723); catalogued as rs781959500, COSV50388321; called by muse, mutect2, varscan2
- SVIL | c.5909C>T p.S1970F (on ENST00000355867 / NM_021738.3; = p.S1544F on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV63442329; called by muse, mutect2, varscan2
- SYNPO2 | c.147G>T p.E49D | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.129); catalogued as COSV61109216; called by muse, mutect2, varscan2
- SYNPO2L | c.1853C>T p.A618V (on ENST00000394810 / NM_001114133.3; = p.A394V on NM_024875.5) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.503); catalogued as COSV65736641; called by muse, mutect2, varscan2
- SYP | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as rs1445131623, COSV54294813; called by muse, mutect2, varscan2
- SZT2 | c.5019G>T p.E1673D (on ENST00000634258 / NM_001365999.1; = p.E1616D on NM_015284.4) | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV65169021; called by muse, mutect2, varscan2
- TAF1 | c.2467C>T p.R823W (on ENST00000373790 / NM_138923.4; = p.R844W on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52111149; called by muse, mutect2, varscan2
- TANGO6 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs536460853, COSV55763499; called by muse, mutect2, varscan2
- TAOK2 | c.1559A>G p.H520R | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54234915; called by muse, mutect2, varscan2
- TCF25 | c.354+8dup | Splice Region (INS) | VAF 39/114 reads (34%) | catalogued as rs1179030417; called by mutect2, pindel, varscan2
- TCF7L1 | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.516); catalogued as COSV56397749; called by muse, mutect2, varscan2
- TCN2 | c.428-2A>G p.X143_splice | Splice Site (SNP) | VAF 13/28 reads (46%) | catalogued as COSV53191097; called by muse, mutect2, varscan2
- TCTN1 | c.1621G>A p.A541T (on ENST00000551590 / NM_001173975.3; = p.A527T on NM_024549.6) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1196601676, COSV54371725; called by muse, mutect2, varscan2
- TCTN2 | c.1691T>C p.L564P | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV57632208; called by muse, mutect2, varscan2
- TEFM | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as rs779707509, COSV60091508; called by muse, mutect2, varscan2
- TENM1 | c.452A>G p.H151R | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV64429792; called by muse, mutect2, varscan2
- TENM3 | c.2245A>G p.S749G | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV69304648; called by muse, mutect2, varscan2
- TFDP1 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64739982; called by muse, mutect2, varscan2
- TG | c.4012T>C p.F1338L | Missense Mutation (SNP) | VAF 106/193 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV55072445; called by muse, mutect2, varscan2
- TGS1 | c.2264T>A p.L755* | Nonsense Mutation (SNP) | VAF 36/203 reads (18%) | catalogued as COSV52699468; called by muse, mutect2, varscan2
- TIMM13 | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV53114110; called by muse, mutect2, varscan2
- TKT | c.1591G>A p.V531M | Missense Mutation (SNP) | VAF 59/104 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs782251102, COSV56245067; called by muse, mutect2, varscan2
- TMEM161B | c.1324G>T p.A442S | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.388); catalogued as COSV56930505; called by muse, mutect2, varscan2
- TNRC18 | c.408del p.S137Afs*105 | Frame Shift Del (DEL) | VAF 9/16 reads (56%) | catalogued as rs1562604447; called by mutect2, pindel, varscan2
- TNRC6B | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773882417, COSV57293204, COSV57295840; called by muse, mutect2, varscan2
- TOP2A | c.4480del p.E1494Rfs*26 | Frame Shift Del (DEL) | VAF 33/102 reads (32%) | catalogued as COSV68503049; called by mutect2, pindel, varscan2
- TP53 | c.1146del p.K382Nfs*40 | Frame Shift Del (DEL) | VAF 90/223 reads (40%) | catalogued as CD126191; called by pindel, varscan2
- TRAP1 | c.1636_1638del p.K546del | In Frame Del (DEL) | VAF 21/46 reads (46%) | catalogued as rs772605434; called by pindel, varscan2
- TRMO | c.826C>A p.P276T | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV64291636; called by muse, mutect2, varscan2
- TRMT10C | c.393del p.K131Nfs*3 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs760928888; called by mutect2, varscan2
- TRMT6 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52543316; called by muse, mutect2
- TSPAN13 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as rs1463014792, COSV50437952; called by muse, mutect2, varscan2
- TTC24 | c.1564A>G p.I522V | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as COSV63997462; called by muse, mutect2, varscan2
- TTLL13P | c.149del p.N50Mfs*17 | Frame Shift Del (DEL) | VAF 7/70 reads (10%) | catalogued as rs773117671; called by mutect2, pindel, varscan2
- TUBG2 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.114); catalogued as COSV52217311; called by muse, mutect2, varscan2
- UBXN10 | c.487T>A p.S163T | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV66772015; called by muse, mutect2, varscan2
- UBXN2B | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as COSV68308898; called by muse, mutect2, varscan2
- UGT3A1 | c.1406C>T p.T469M | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as rs370982147; called by muse, mutect2, varscan2
- UPF2 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 64/795 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs761790852, COSV62659917; called by muse, mutect2
- UROS | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV64223508; called by muse, mutect2, varscan2
- USP34 | c.7984C>T p.Q2662* | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as COSV68400213; called by muse, mutect2, varscan2
- USP45 | c.1220C>T p.T407I | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.444); catalogued as rs1254295043, COSV59679987; called by muse, mutect2
- USP5 | c.789G>T p.E263D | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57536478; called by muse, mutect2, varscan2
- VEPH1 | c.1661del p.N554Tfs*5 | Frame Shift Del (DEL) | VAF 90/208 reads (43%) | catalogued as rs756863093; called by mutect2, varscan2
- VSTM4 | c.522del p.F174Lfs*39 | Frame Shift Del (DEL) | VAF 60/135 reads (44%) | catalogued as rs1308173148; called by mutect2, pindel, varscan2
- WDR11 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.985); catalogued as rs747370432, COSV54787395; called by muse, mutect2, varscan2
- WDR19 | c.1534C>T p.R512* | Nonsense Mutation (SNP) | VAF 8/96 reads (8%) | catalogued as rs1476588496, COSV56463923; called by muse, mutect2
- WDR45 | c.700G>C p.G234R (on ENST00000376372 / NM_001029896.2; = p.G235R on NM_007075.3) | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD1211575, COSV59875819; called by muse, mutect2, varscan2
- WDR59 | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV50934674; called by muse, mutect2, varscan2
- WDTC1 | c.1759C>T p.Q587* (on ENST00000319394 / NM_001276252.2; = p.Q586* on NM_015023.5) | Nonsense Mutation (SNP) | VAF 15/27 reads (56%) | catalogued as COSV60087973; called by muse, mutect2, varscan2
- WFDC12 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.873); catalogued as rs144241239; called by muse, mutect2, varscan2
- WFIKKN1 | c.206T>A p.V69E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50193276; called by muse, mutect2, varscan2
- WIPI1 | c.1038G>T p.Q346H | Missense Mutation (SNP) | VAF 4/99 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.593); catalogued as COSV50929821; called by muse, mutect2
- WNK3 | c.638G>T p.W213L | Missense Mutation (SNP) | VAF 106/227 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63613163; called by muse, mutect2, varscan2
- WNT16 | c.500del p.G167Afs*17 (on ENST00000222462 / NM_057168.2; = p.G157Afs*17 on NM_016087.2) | Frame Shift Del (DEL) | VAF 19/40 reads (48%) | catalogued as rs771899177; called by mutect2, pindel, varscan2
- XPNPEP2 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 33/54 reads (61%) | catalogued as rs778237185, COSV64367850; called by muse, mutect2, varscan2
- ZC3H11A | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.821); catalogued as COSV59745625; called by muse, mutect2, varscan2
- ZDHHC5 | c.1919A>C p.Q640P | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs773251350, COSV54706190; called by muse, mutect2, varscan2
- ZEB2 | c.1903C>A p.L635I | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.338); catalogued as COSV57955143; called by muse, mutect2, varscan2
- ZFHX4 | c.1230dup p.L411Afs*3 | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | catalogued as rs761578656; called by mutect2, varscan2
- ZNF292 | c.6145del p.S2049Vfs*11 | Frame Shift Del (DEL) | VAF 30/62 reads (48%) | catalogued as rs764995318; called by mutect2, varscan2
- ZNF318 | c.2783G>A p.R928H | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58931742; called by muse, mutect2
- ZNF326 | c.899del p.N300Tfs*41 | Frame Shift Del (DEL) | VAF 45/101 reads (45%) | catalogued as rs770970244; called by mutect2, pindel, varscan2
- ZNF416 | c.1225C>A p.P409T | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV52184004; called by muse, mutect2, varscan2
- ZNF462 | c.4115G>T p.R1372M | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV52935343; called by muse, mutect2, varscan2
- ZNF572 | c.578G>A p.C193Y | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60001667; called by muse, mutect2, varscan2
- ZNF610 | c.1168C>A p.H390N | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58344372; called by muse, mutect2
- ZNF674 | c.1643C>T p.T548I | Missense Mutation (SNP) | VAF 125/274 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV70378882; called by muse, mutect2, varscan2
- ZNF785 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs201848622, COSV67876261; called by muse, mutect2, varscan2
- ZSWIM8 | c.5085del p.Y1696Tfs*17 (on ENST00000605216 / NM_001242487.2; = p.Y1701Tfs*17 on NM_015037.3) | Frame Shift Del (DEL) | VAF 32/54 reads (59%) | catalogued as rs769663113; called by mutect2, varscan2
- AARS2 | c.1709del p.G570Afs*21 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel
- ADD2 | c.727del p.L243Sfs*45 | Frame Shift Del (DEL) | VAF 22/49 reads (45%) | called by mutect2, pindel, varscan2
- ANK2 | c.161dup p.I55Hfs*41 | Frame Shift Ins (INS) | VAF 24/64 reads (38%) | called by mutect2, pindel, varscan2
- ARHGAP17 | c.2156del p.P719Lfs*7 (on ENST00000289968 / NM_001006634.3; = p.P641Lfs*7 on NM_018054.6) | Frame Shift Del (DEL) | VAF 24/57 reads (42%) | called by mutect2, pindel, varscan2
- ARID1A | c.2198dup p.D734Gfs*83 | Frame Shift Ins (INS) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- ARID4B | c.2815del p.T939Rfs*2 | Frame Shift Del (DEL) | VAF 54/119 reads (45%) | called by mutect2, pindel, varscan2
- ASPM | c.5039del p.N1680Mfs*4 | Frame Shift Del (DEL) | VAF 39/173 reads (23%) | called by mutect2, pindel, varscan2
- ATP6AP1 | c.1150_1152del p.L384del | In Frame Del (DEL) | VAF 16/23 reads (70%) | called by pindel, varscan2
- ATRIP | c.1033del p.L345Cfs*31 | Frame Shift Del (DEL) | VAF 28/78 reads (36%) | called by mutect2, pindel, varscan2
- AUP1 | c.459del p.T154Lfs*46 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, pindel, varscan2
- C12orf40 | c.557del p.K186Sfs*19 | Frame Shift Del (DEL) | VAF 61/140 reads (44%) | called by mutect2, pindel, varscan2
- C12orf66 | c.1020del p.K341Rfs*9 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- CEP350 | c.8666del p.N2889Ifs*10 | Frame Shift Del (DEL) | VAF 50/161 reads (31%) | called by mutect2, pindel, varscan2
- COBL | c.130del p.A44Pfs*11 | Frame Shift Del (DEL) | VAF 9/18 reads (50%) | called by mutect2, varscan2
- COL8A1 | c.1795del p.H599Mfs*24 | Frame Shift Del (DEL) | VAF 9/18 reads (50%) | called by mutect2, varscan2
- CYTH3 | c.1200del p.K400Nfs*6 (on ENST00000396741; = p.K399Nfs*6 on NM_004227.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 82/225 reads (36%) | called by mutect2, pindel, varscan2
- DMXL2 | c.7474dup p.S2492Ffs*15 | Frame Shift Ins (INS) | VAF 74/153 reads (48%) | called by mutect2, varscan2
- DNAH11 | c.4650del p.F1550Lfs*12 | Frame Shift Del (DEL) | VAF 29/136 reads (21%) | called by mutect2, pindel, varscan2
- DNAH8 | c.1538dup p.I514Yfs*17 | Frame Shift Ins (INS) | VAF 20/76 reads (26%) | called by pindel, varscan2
- DYRK1A | c.1236del p.K412Nfs*39 | Frame Shift Del (DEL) | VAF 48/119 reads (40%) | called by mutect2, pindel, varscan2
- F5 | c.3912_3913dup p.P1305Lfs*29 | Frame Shift Ins (INS) | VAF 245/442 reads (55%) | called by mutect2, varscan2
- FIBIN | c.202dup p.E68Gfs*72 | Frame Shift Ins (INS) | VAF 6/19 reads (32%) | called by mutect2, varscan2
- FRMPD4 | c.3144del p.K1048Nfs*29 | Frame Shift Del (DEL) | VAF 29/71 reads (41%) | called by mutect2, pindel, varscan2
- GABRB3 | c.508del p.L170Wfs*66 | Frame Shift Del (DEL) | VAF 68/169 reads (40%) | called by mutect2, pindel, varscan2
- GABRQ | c.1751dup p.S585Kfs*8 | Frame Shift Ins (INS) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- GINS4 | c.428dup p.N143Kfs*10 | Frame Shift Ins (INS) | VAF 19/43 reads (44%) | called by mutect2, pindel, varscan2
- GNAZ | c.612del p.Q205Rfs*29 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- GTF2B | c.926del p.P309Qfs*18 | Frame Shift Del (DEL) | VAF 14/130 reads (11%) | called by mutect2, pindel
- HELZ | c.4296del p.F1432Lfs*17 | Frame Shift Del (DEL) | VAF 70/161 reads (43%) | called by mutect2, pindel, varscan2
- HERC1 | c.3784dup p.T1262Nfs*4 | Frame Shift Ins (INS) | VAF 70/169 reads (41%) | called by mutect2, pindel, varscan2
- HGF | c.189dup p.V64Sfs*9 | Frame Shift Ins (INS) | VAF 56/556 reads (10%) | called by mutect2, pindel, varscan2
- HMGCR | c.1085del p.K362Rfs*24 | Frame Shift Del (DEL) | VAF 42/112 reads (38%) | called by mutect2, pindel, varscan2
- ITGA4 | c.385del p.V129Sfs*14 | Frame Shift Del (DEL) | VAF 72/174 reads (41%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 58/118 reads (49%) | called by mutect2, varscan2
- JHY | c.841del p.R281Efs*15 | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | called by mutect2, pindel, varscan2
- KANSL1L | c.245del p.L82* | Frame Shift Del (DEL) | VAF 41/189 reads (22%) | called by mutect2, pindel, varscan2
- KLHL38 | c.1261del p.V421Cfs*8 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- KNTC1 | c.1661dup p.L554Ffs*23 | Frame Shift Ins (INS) | VAF 84/187 reads (45%) | called by mutect2, varscan2
- LAMP3 | c.766dup p.S256Ffs*43 | Frame Shift Ins (INS) | VAF 37/83 reads (45%) | called by mutect2, pindel, varscan2
- LYST | c.9773del p.L3258* | Frame Shift Del (DEL) | VAF 19/146 reads (13%) | called by mutect2, pindel, varscan2
- MAP7D2 | c.1868del p.G623Dfs*27 | Frame Shift Del (DEL) | VAF 59/138 reads (43%) | called by mutect2, pindel, varscan2
- MLXIP | c.1388del p.P463Rfs*46 | Frame Shift Del (DEL) | VAF 28/61 reads (46%) | called by mutect2, pindel, varscan2
- MYCBPAP | c.1317_1319del p.S440del | In Frame Del (DEL) | VAF 14/46 reads (30%) | called by pindel, varscan2
- MYF6 | c.129del p.C44Afs*35 | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | called by pindel, varscan2
- MYH3 | c.249del p.K84Sfs*11 | Frame Shift Del (DEL) | VAF 25/67 reads (37%) | called by mutect2, pindel, varscan2
- NEXN | c.717del p.E240Nfs*8 | Frame Shift Del (DEL) | VAF 25/107 reads (23%) | called by mutect2, pindel, varscan2
- NUCB2 | c.1200dup p.L401Ifs*17 | Frame Shift Ins (INS) | VAF 38/94 reads (40%) | called by mutect2, varscan2
- OGT | c.2112del p.F704Lfs*12 | Frame Shift Del (DEL) | VAF 85/223 reads (38%) | called by mutect2, pindel, varscan2
- OR13C2 | c.39del p.L14* | Frame Shift Del (DEL) | VAF 32/92 reads (35%) | called by mutect2, pindel, varscan2
- OTULINL | c.691dup p.S231Ffs*8 | Frame Shift Ins (INS) | VAF 59/148 reads (40%) | called by mutect2, pindel, varscan2
- PCDHB2 | c.1353del p.A452Pfs*92 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | called by mutect2, pindel, varscan2
- PMP2 | c.81del p.L28* | Frame Shift Del (DEL) | VAF 128/332 reads (39%) | called by mutect2, pindel, varscan2
- POSTN | c.542del p.N181Mfs*3 | Frame Shift Del (DEL) | VAF 78/196 reads (40%) | called by mutect2, pindel, varscan2
- PTCH1 | c.3606del p.S1203Afs*52 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | called by mutect2, pindel, varscan2
- PTEN | c.178_191del p.K60Lfs*9 | Frame Shift Del (DEL) | VAF 121/135 reads (90%) | called by mutect2, pindel, varscan2
- RASL10B | c.190A>G p.S64G | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM45 | c.1363del p.V455* (on ENST00000616198 / NM_001365579.1; = p.V453* on NM_152945.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 63/171 reads (37%) | called by mutect2, pindel, varscan2
- RGL1 | c.1748del p.K583Sfs*25 (on ENST00000360851 / NM_001297672.2; = p.K618Sfs*25 on NM_015149.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 19/45 reads (42%) | called by mutect2, pindel, varscan2
- ROCK1 | c.3448del p.I1150Ffs*21 | Frame Shift Del (DEL) | VAF 65/169 reads (38%) | called by mutect2, pindel, varscan2
- SENP6 | c.3009del p.G1004Efs*11 | Frame Shift Del (DEL) | VAF 52/147 reads (35%) | called by mutect2, pindel, varscan2
- SEPTIN12 | c.24del p.S9Lfs*31 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- SIPA1L1 | c.172dup p.R58Pfs*3 | Frame Shift Ins (INS) | VAF 16/37 reads (43%) | called by mutect2, varscan2
- SLC4A11 | c.252del p.F84Lfs*32 | Frame Shift Del (DEL) | VAF 20/44 reads (45%) | called by mutect2, pindel, varscan2
- SLFN13 | c.1027dup p.T343Nfs*2 | Frame Shift Ins (INS) | VAF 43/117 reads (37%) | called by mutect2, pindel, varscan2
- SMC2 | c.3136del p.S1046Lfs*37 | Frame Shift Del (DEL) | VAF 55/151 reads (36%) | called by mutect2, pindel, varscan2
- SPDYA | c.703del p.R235Efs*21 | Frame Shift Del (DEL) | VAF 32/76 reads (42%) | called by mutect2, pindel, varscan2
- SPTBN2 | c.3639del p.K1213Nfs*6 | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | called by mutect2, pindel, varscan2
- STAB1 | c.3364del p.R1122Efs*108 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | called by mutect2, pindel, varscan2
- SYK | c.496del p.M166Cfs*18 | Frame Shift Del (DEL) | VAF 43/106 reads (41%) | called by mutect2, pindel, varscan2
- TAF4B | c.540del p.K180Nfs*5 | Frame Shift Del (DEL) | VAF 39/106 reads (37%) | called by mutect2, pindel, varscan2
- TAS2R41 | c.588del p.L197Wfs*7 | Frame Shift Del (DEL) | VAF 11/95 reads (12%) | called by mutect2, varscan2
- TDRD1 | c.3459del p.K1153Nfs*10 | Frame Shift Del (DEL) | VAF 114/270 reads (42%) | called by mutect2, pindel, varscan2
- TENM3 | c.2082del p.T695Rfs*81 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- TIMM23 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TM6SF1 | c.1007dup p.L336Ffs*46 | Frame Shift Ins (INS) | VAF 44/115 reads (38%) | called by mutect2, varscan2
- TMEM44 | c.908_909del p.A303Gfs*32 (on ENST00000392432 / NM_001166305.2; = p.A256Gfs*32 on NM_138399.5) | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- TRPM7 | c.5396_5398del p.G1799del | In Frame Del (DEL) | VAF 89/202 reads (44%) | called by mutect2, pindel, varscan2
- TRRAP | c.3479del p.G1160Vfs*25 | Frame Shift Del (DEL) | VAF 44/124 reads (35%) | called by mutect2, pindel, varscan2
- UBE2E3 | c.109del p.E37Kfs*34 | Frame Shift Del (DEL) | VAF 35/91 reads (38%) | called by mutect2, pindel, varscan2
- UBR4 | c.8406del p.M2803Cfs*16 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- UGT1A9 | c.677dup p.N226Kfs*8 | Frame Shift Ins (INS) | VAF 58/158 reads (37%) | called by mutect2, pindel, varscan2
- UGT2B4 | c.1428dup p.R477Sfs*44 | Frame Shift Ins (INS) | VAF 68/167 reads (41%) | called by mutect2, pindel, varscan2
- USF3 | c.439dup p.I147Nfs*25 | Frame Shift Ins (INS) | VAF 35/82 reads (43%) | called by mutect2, varscan2
- WDFY3 | c.1359del p.F453Lfs*3 | Frame Shift Del (DEL) | VAF 43/124 reads (35%) | called by mutect2, pindel, varscan2
- WNT5A | c.228_229del p.Q77Rfs*43 | Frame Shift Del (DEL) | VAF 32/74 reads (43%) | called by pindel, varscan2
- ABCA8 | c.3897C>T p.D1299= | Silent (SNP) | VAF 117/267 reads (44%) | catalogued as COSV52199101; called by muse, mutect2, varscan2
- ABCC1 | c.2580C>T p.G860= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs367802550; called by muse, mutect2
- ADAM12 | c.1680C>T p.G560= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as rs746184798, COSV64104943; called by muse, mutect2, varscan2
- ADRA2B | c.1044C>T p.G348= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs772052755, COSV69787388; called by muse, mutect2, varscan2
- ANKAR | c.2229C>T p.T743= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as rs773004055, COSV55611490; called by muse, mutect2, varscan2
- ANKAR | c.2328G>A p.V776= | Silent (SNP) | VAF 51/116 reads (44%) | catalogued as COSV55611505; called by muse, mutect2, varscan2
- APEX2 | c.801C>A p.A267= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV58189613, COSV58193050; called by muse, mutect2
- ATP6V1G1 | c.267G>A p.R89= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs1486121461, COSV65014064; called by muse, mutect2, varscan2
- C17orf75 | c.705A>G p.S235= | Silent (SNP) | VAF 30/466 reads (6%) | catalogued as COSV56752626; called by muse, mutect2
- CA3 | c.195C>A p.T65= | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as COSV53409653; called by muse, mutect2, varscan2
- CAPRIN2 | c.2172G>A p.L724= | Silent (SNP) | VAF 208/467 reads (45%) | catalogued as COSV51831902; called by muse, mutect2, varscan2
- CDCA7 | c.1050T>C p.Y350= (on ENST00000347703 / NM_145810.3; = p.Y429= on NM_031942.5) | Silent (SNP) | VAF 79/186 reads (42%) | catalogued as COSV60720231; called by muse, mutect2, varscan2
- CEP57 | c.267G>A p.Q89= | Silent (SNP) | VAF 44/106 reads (42%) | catalogued as COSV57688017; called by muse, mutect2, varscan2
- CEP76 | c.1371T>C p.G457= | Silent (SNP) | VAF 29/153 reads (19%) | catalogued as COSV50866061; called by muse, mutect2, varscan2
- CHAD | c.981C>T p.A327= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV51971981; called by muse, mutect2, varscan2
- CRYBG1 | c.5400C>T p.G1800= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV64811720; called by muse, mutect2, varscan2
- CSF1R | c.1800G>A p.T600= | Silent (SNP) | VAF 57/137 reads (42%) | catalogued as rs369426734; called by muse, mutect2, varscan2
- DCDC1 | c.1861C>T p.L621= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV60839656; called by muse, mutect2
- DEAF1 | c.1320G>A p.A440= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs187523180; ClinVar: likely benign; called by muse, mutect2, varscan2
- DLG5 | c.1869C>T p.F623= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs556899023, COSV64947573; called by muse, mutect2, varscan2
- DOCK1 | c.2127G>A p.T709= | Silent (SNP) | VAF 82/197 reads (42%) | catalogued as rs781005154, COSV54736322; called by muse, mutect2, varscan2
- DRD1 | c.10C>T p.L4= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV67104453; called by muse, mutect2, varscan2
- DTNA | c.1845T>C p.N615= | Silent (SNP) | VAF 64/133 reads (48%) | catalogued as COSV51998983; called by muse, mutect2, varscan2
- DTX3L | c.804G>A p.Q268= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV56143910; called by muse, mutect2, varscan2
- EIF3E | c.813G>A p.R271= | Silent (SNP) | VAF 65/139 reads (47%) | catalogued as rs936856066, COSV55202368; called by muse, mutect2, varscan2
- ELMOD2 | c.360T>C p.Y120= | Silent (SNP) | VAF 96/214 reads (45%) | catalogued as rs1346333541, COSV60270305; called by muse, mutect2, varscan2
- EPAS1 | c.2022C>A p.P674= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV55385745; called by muse, mutect2, varscan2
- EPHA6 | c.2961C>T p.Y987= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as COSV67568253; called by muse, mutect2, varscan2
- ESRP1 | c.147C>T p.H49= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs377762593; called by muse, mutect2, varscan2
- EVPL | c.549C>T p.N183= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs1275534820, COSV56909694; called by muse, mutect2, varscan2
- EWSR1 | c.66C>T p.T22= | Silent (SNP) | VAF 159/316 reads (50%) | catalogued as rs377732811; called by muse, mutect2, varscan2
- FAM131B | c.915T>C p.S305= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV58369034; called by muse, mutect2
- FBXL2 | c.253T>C p.L85= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV52138079; called by muse, mutect2, varscan2
- FBXW4 | c.1377T>C p.P459= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV58707465; called by muse, mutect2, varscan2
- FGD3 | c.249C>A p.S83= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV61596742; called by muse, mutect2, varscan2
- FRG2C | c.399G>A p.V133= | Silent (SNP) | VAF 24/151 reads (16%) | called by muse, mutect2, varscan2
- FRMPD1 | c.2025C>T p.S675= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs533913734, COSV66700015; called by muse, mutect2, varscan2
- FRY | c.4647T>C p.A1549= | Silent (SNP) | VAF 74/163 reads (45%) | catalogued as COSV66568398; called by muse, mutect2, varscan2
- FUT1 | c.717C>T p.S239= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as COSV59568052; called by muse, mutect2, varscan2
- FZD7 | c.792C>T p.C264= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as COSV53809050; called by mutect2, varscan2
- GABRA1 | c.867T>G p.T289= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as COSV50102066; called by muse, mutect2, varscan2
- HEATR9 | c.984A>G p.P328= | Silent (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- HIVEP1 | c.1914C>T p.H638= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as rs778495637, COSV65100472; called by muse, mutect2, varscan2
- HIVEP3 | c.6231C>T p.A2077= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs747687098, COSV56013514; called by muse, mutect2, varscan2
- HOXB1 | c.60C>T p.S20= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs537215928, COSV53316969; called by muse, mutect2, varscan2
- HOXD13 | c.573C>A p.S191= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV66832505; called by muse, mutect2, varscan2
- HTRA3 | c.510G>A p.V170= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV56469597; called by muse, mutect2, varscan2
- IGSF22 | c.1743C>T p.G581= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs772992615, COSV60032911; called by muse, mutect2, varscan2
- IQCB1 | c.1548C>A p.T516= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV60436937; called by muse, mutect2, varscan2
- IQCE | c.1302C>T p.C434= | Silent (SNP) | VAF 57/129 reads (44%) | catalogued as rs533844835, COSV58077669, COSV58078866; called by muse, mutect2, varscan2
- IRGQ | c.843C>T p.H281= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV60670508; called by muse, mutect2, varscan2
- ITGA11 | c.1503C>T p.G501= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs550754461, COSV59876759; called by muse, mutect2, varscan2
- JAKMIP3 | c.1263C>T p.A421= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs773930187, COSV53822137; called by muse, mutect2, varscan2
- KATNIP | c.4602C>T p.S1534= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV55178382; called by muse, mutect2, varscan2
- KCNA6 | c.1296T>C p.T432= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as COSV54974794; called by muse, mutect2, varscan2
- KIF20A | c.507G>A p.T169= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs375606679; called by muse, mutect2, varscan2
- KIRREL3 | c.486G>A p.A162= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs753719353, COSV73104930; called by muse, mutect2, varscan2
- L3MBTL1 | c.1197C>T p.Y399= (on ENST00000418998 / NM_001377303.1; = p.Y309= on NM_015478.7) | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV64228251; called by muse, mutect2, varscan2
- LRRC8E | c.280T>C p.L94= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV60717669; called by muse, mutect2, varscan2
- LRRK2 | c.5109A>G p.G1703= | Silent (SNP) | VAF 89/202 reads (44%) | catalogued as COSV54149858; called by muse, mutect2, varscan2
- LRTM1 | c.456G>A p.A152= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as rs376696012; called by muse, mutect2, varscan2
- LSMEM2 | c.186C>T p.R62= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV57113328; called by muse, mutect2, varscan2
- MORC1 | c.1818T>C p.H606= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as COSV51717861; called by muse, mutect2, varscan2
- MYF6 | c.171C>T p.S57= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV57351299; called by muse, varscan2
- MYH10 | c.768C>T p.I256= | Silent (SNP) | VAF 58/134 reads (43%) | catalogued as rs1431889632, COSV52595916; called by muse, mutect2, varscan2
- MYO18B | c.3030C>T p.T1010= | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as rs1395401513, COSV59131187; called by muse, mutect2, varscan2
- N4BP2 | c.5058G>A p.L1686= | Silent (SNP) | VAF 68/128 reads (53%) | catalogued as rs566339817, COSV54700974, COSV54702121; called by muse, mutect2, varscan2
- NCOA2 | c.3891G>A p.Q1297= | Silent (SNP) | VAF 66/142 reads (46%) | catalogued as COSV51218947; called by muse, mutect2, varscan2
- NFXL1 | c.327T>C p.S109= | Silent (SNP) | VAF 140/290 reads (48%) | catalogued as COSV61198618; called by muse, mutect2, varscan2
- NLRP1 | c.3669T>C p.H1223= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV52563771; called by muse, mutect2
- NLRP14 | c.2106T>C p.C702= | Silent (SNP) | VAF 53/111 reads (48%) | catalogued as COSV55065925; called by muse, mutect2, varscan2
- NUP153 | c.3177A>G p.S1059= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as COSV50448213, COSV50450471; called by muse, mutect2, varscan2
- OR5H2 | c.513A>G p.L171= | Silent (SNP) | VAF 73/166 reads (44%) | catalogued as COSV62350546; called by muse, mutect2, varscan2
- PBX3 | c.810G>A p.E270= | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as COSV60731662; called by muse, mutect2, varscan2
- PCDHA13 | c.183G>A p.P61= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV56493090; called by muse, mutect2, varscan2
- PCDHA13 | c.1929G>A p.P643= | Silent (SNP) | VAF 5/8 reads (63%) | catalogued as rs146010500, COSV99165049; called by muse, mutect2
- PCDHB12 | c.1443C>T p.G481= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV53395346; called by muse, mutect2, varscan2
- PCDHGB1 | c.753C>T p.N251= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as rs767340665, COSV53929025; called by muse, mutect2, varscan2
- PCED1B | c.1135C>T p.L379= | Silent (SNP) | VAF 44/85 reads (52%) | catalogued as COSV71395093; called by muse, mutect2, varscan2
- PCYT1A | c.18A>G p.S6= | Silent (SNP) | VAF 50/135 reads (37%) | catalogued as COSV53057104; called by muse, mutect2, varscan2
- PDCD7 | c.951C>T p.D317= | Silent (SNP) | VAF 111/233 reads (48%) | catalogued as COSV52600219; called by muse, mutect2, varscan2
- PJA1 | c.942T>C p.S314= (on ENST00000361478 / NM_145119.4; = p.S126= on NM_022368.5) | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV64052929; called by muse, mutect2, varscan2
- PLK3 | c.366C>T p.I122= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV59499590; called by muse, mutect2, varscan2
- PLXNA4 | c.1722C>T p.N574= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs759386370, COSV58117902, COSV58155656; called by muse, mutect2, varscan2
- POM121 | c.1407A>G p.P469= (on ENST00000434423; = p.P204= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/330 reads (3%) | catalogued as COSV57514124; called by muse, mutect2
- POU4F2 | c.414G>A p.P138= | Silent (SNP) | VAF 60/105 reads (57%) | catalogued as rs1484810723, COSV55583766; called by muse, mutect2, varscan2
- POU4F2 | c.1128C>T p.A376= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs200415873; called by muse, mutect2, varscan2
- PPEF2 | c.1548C>T p.G516= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV54421701; called by muse, mutect2, varscan2
- PPIAL4A | c.123T>C p.T41= | Silent (SNP) | VAF 64/151 reads (42%) | called by muse, mutect2, varscan2
- PRKG2 | c.1074A>G p.K358= | Silent (SNP) | VAF 20/360 reads (6%) | catalogued as COSV52322657; called by muse, mutect2
- PRR23B | c.402C>T p.D134= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV61493484; called by muse, mutect2, varscan2
- PTPN11 | c.984T>C p.I328= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs1473974132, COSV61007980; called by muse, mutect2
- PTPN14 | c.1920C>A p.R640= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV65283259; called by muse, mutect2, varscan2
- PTPRH | c.1410C>T p.S470= | Silent (SNP) | VAF 54/104 reads (52%) | catalogued as rs1245729782, COSV54744483; called by muse, mutect2, varscan2
- PUM1 | c.1263C>T p.P421= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs267598545; called by muse, mutect2, varscan2
- REEP3 | c.705C>T p.R235= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as COSV53424129; called by muse, mutect2, varscan2
- RPN2 | c.1464C>A p.A488= | Silent (SNP) | VAF 36/64 reads (56%) | catalogued as COSV52904992; called by muse, mutect2, varscan2
- RPS6KL1 | c.141T>A p.R47= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV63580981; called by muse, mutect2, varscan2
- RUBCNL | c.1656G>A p.V552= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV59787328; called by muse, mutect2, varscan2
- SHISA2 | c.699C>T p.T233= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV60110526; called by muse, mutect2, varscan2
- SIDT1 | c.447C>T p.V149= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs757199013, COSV53500155; called by muse, mutect2, varscan2
- SLF1 | c.2070T>C p.C690= | Silent (SNP) | VAF 80/164 reads (49%) | catalogued as COSV54369093; called by muse, mutect2, varscan2
- SPATA31E1 | c.3342C>T p.G1114= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV57790799; called by muse, mutect2
- SPEN | c.2631C>T p.C877= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as rs762589812, COSV65360453; called by muse, mutect2, varscan2
- STRAP | c.891A>T p.G297= | Silent (SNP) | VAF 59/111 reads (53%) | catalogued as COSV50308411; called by muse, mutect2, varscan2
- SYNM | c.2271C>T p.S757= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as rs368374457; called by muse, mutect2, varscan2
- TANGO6 | c.2220C>T p.L740= | Silent (SNP) | VAF 98/201 reads (49%) | catalogued as rs369216490, COSV55763521; called by muse, mutect2, varscan2
- TCF20 | c.939G>A p.Q313= | Silent (SNP) | VAF 38/67 reads (57%) | catalogued as rs1252519239, COSV59490230; called by muse, mutect2, varscan2
- TIMELESS | c.1950C>A p.L650= | Silent (SNP) | VAF 40/99 reads (40%) | catalogued as COSV57510573, COSV57513003; called by muse, mutect2, varscan2
- TMEM185A | c.691C>T p.L231= | Silent (SNP) | VAF 32/116 reads (28%) | called by muse, mutect2, varscan2
- TMEM53 | c.705C>G p.R235= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV59190311; called by mutect2, varscan2
- TMEM92 | c.447G>T p.G149= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as COSV55946201; called by muse, mutect2, varscan2
- TRAF3 | c.648C>T p.S216= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs1419813524, COSV61024698, COSV61025951; called by muse, mutect2, varscan2
- TRPS1 | c.3375G>A p.P1125= (on ENST00000220888 / NM_001330599.2; = p.P1138= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/146 reads (53%) | catalogued as rs775507790, COSV55235309, COSV55239652; called by muse, mutect2, varscan2
- TTC17 | c.891C>T p.S297= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as COSV50006581; called by muse, mutect2, varscan2
- TTC25 | c.1122G>A p.G374= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV66367867; called by muse, mutect2, varscan2
- TTN | c.85491G>A p.G28497= (on ENST00000591111; = p.G21073= on NM_003319.4) | Silent (SNP) | VAF 10/152 reads (7%) | catalogued as COSV59988842; called by muse, mutect2
- UBE4B | c.996C>T p.P332= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV53530304; called by muse, mutect2, varscan2
- UBXN11 | c.54G>A p.S18= | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as rs753300494, COSV59025414; called by muse, mutect2, varscan2
- UTP20 | c.2532G>A p.P844= | Silent (SNP) | VAF 28/48 reads (58%) | catalogued as rs768715409, COSV55375255; called by muse, mutect2, varscan2
- VDAC1 | c.771G>A p.L257= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV51548259; called by muse, mutect2
- WDFY3 | c.4461T>C p.H1487= | Silent (SNP) | VAF 66/112 reads (59%) | catalogued as COSV55698555; called by muse, mutect2, varscan2
- ZBED1 | c.1299G>A p.T433= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as rs772761841, COSV58130855; called by muse, mutect2, varscan2
- ZBTB22 | c.1377G>A p.T459= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as rs749582553, COSV56467988; called by muse, mutect2, varscan2
- ZCCHC7 | c.741C>T p.D247= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as COSV60956390; called by muse, mutect2, varscan2
- ZIC3 | c.1134C>T p.H378= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV54973538; called by muse, mutect2, varscan2
- ZNF17 | c.1125T>C p.I375= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV56921169; called by muse, mutect2, varscan2
- ZNF532 | c.1044G>A p.P348= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as rs777310864, COSV60172606; called by muse, mutect2, varscan2
- ZNF627 | c.1179T>C p.C393= | Silent (SNP) | VAF 35/61 reads (57%) | catalogued as COSV63142082; called by muse, mutect2, varscan2
- ZNF749 | c.1929T>C p.S643= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as rs1039094856, COSV61945767; called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+16del | Intron (DEL) | VAF 63/185 reads (34%) | catalogued as rs766264675; called by pindel, varscan2
- KIAA0930 | c.853-930del | Intron (DEL) | VAF 16/42 reads (38%) | catalogued as rs764079139; called by mutect2, pindel, varscan2
- MFSD4B | c.*186del | 3'UTR (DEL) | VAF 26/214 reads (12%) | catalogued as rs540972233; called by mutect2, varscan2
- POLA1 | c.2947-21222del | Intron (DEL) | VAF 90/225 reads (40%) | called by mutect2, pindel, varscan2
- RPL12 | c.293-143C>A | Intron (SNP) | VAF 12/24 reads (50%) | catalogued as COSV55939505; called by muse, mutect2
- SLC25A25 | c.262-9054del | Intron (DEL) | VAF 14/36 reads (39%) | called by mutect2, pindel, varscan2
- SLC2A9 | chr4:10025916 C>T | 5'Flank (SNP) | VAF 189/379 reads (50%) | catalogued as rs1358496583, COSV53319316; called by muse, varscan2
- ST6GALNAC6 | c.*74del | 3'UTR (DEL) | VAF 5/12 reads (42%) | called by mutect2, varscan2
- STON1 | chr2:48529578 G>A | 5'Flank (SNP) | VAF 35/86 reads (41%) | called by muse, mutect2, varscan2
- TPD52L2 | c.477-1592G>A | Intron (SNP) | VAF 22/34 reads (65%) | catalogued as COSV53862155; called by muse, mutect2, varscan2
- TRAC | c.*404del | 3'UTR (DEL) | VAF 42/90 reads (47%) | catalogued as rs754035003; called by mutect2, varscan2
- ZSWIM4 | chr19:13836313 G>A | 3'Flank (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
